Gene-level copy-number profile of tumor specimen TCGA-61-2613-01A from TCGA case TCGA-61-2613, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 73.3 years (26,779 days).
Specimen TCGA-61-2613-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.cf6b6185-cf35-43b2-a7f2-8544fadccedf.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-61-2613-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ce77fdc5-f9d1-4a6d-83e1-b68d28b89ff3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 16,963; copy number 2: 39,044; copy number 3: 2,887; copy number 4: 746; copy number 5: 57; copy number 6: 90; copy number 9: 23.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-61-2613-01A-01D-1134-01): tumor purity 0.73, ploidy 1.86, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 170 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:141,876,124–142,713,664, 19 genes, copy number 6 (within-gene range 3–6): ATP1B3, RNU6-509P, ATP1B3-AS1, AC112504.1, TFDP2, AC133435.1, RNU6-425P, GK5, XRN1, RNU6-1294P, RNU1-100P, ATR, AC109992.1, AC109992.2, RPL6P9, RNA5SP143, PLS1, PLS1-AS1, RN7SKP25.
- chr6:31,580,525–31,969,751, 57 genes, copy number 5: LTB, LST1, NCR3, UQCRHP1, AIF1, PRRC2A, SNORA38, MIR6832, BAG6, APOM, C6orf47, C6orf47-AS1, GPANK1, Y_RNA, CSNK2B, AL662899.2, LY6G5B, LY6G5C, ABHD16A, AL662899.1, MIR4646, LY6G6F, LY6G6F-LY6G6D, LY6G6E, LY6G6D, MPIG6B, LY6G6C, DDAH2, CLIC1, MSH5, MSH5-SAPCD1, RNU6-850P, SAPCD1, SAPCD1-AS1, VWA7, VARS1, Y_RNA, LSM2, HSPA1L, HSPA1A, HSPA1B, AL671762.1, SNHG32, SNORD48, SNORD52, NEU1, SLC44A4, EHMT2-AS1, EHMT2, C2, ZBTB12, AL645922.1, C2-AS1, CFB, NELFE, MIR1236, SKIV2L.
- chr19:8,695,721–10,339,661, 94 genes, copy number 6–9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 14,542. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
